Somatic mutation profile of tumor specimen TCGA-P3-A6T0-01A (aliquot TCGA-P3-A6T0-01A-12D-A34J-08) from TCGA case TCGA-P3-A6T0, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 47.3 years (17,259 days).
Specimen TCGA-P3-A6T0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0214c282-7c54-4e5a-9341-f86c7a8fc6b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P3-A6T0-10A (Blood Derived Normal), aliquot TCGA-P3-A6T0-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c87a39ea-7a91-4762-afb3-17b89ecd93dc

The open-access MAF lists 90 somatic variants for this specimen: 69 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 20, Nonsense Mutation 8, In Frame Del 2, Frame Shift Ins 1, Frame Shift Del 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF2 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 22/48 reads (46%) | catalogued as rs74315495, CM941100, COSV58519836, COSV58528035; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 32/100 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.752T>A p.I251N | Missense Mutation (SNP) | VAF 28/101 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs730882027, COSV52728902, COSV52741592, COSV52816233, COSV53108676; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 26/90 reads (29%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC131160.1 | c.297A>G p.I99M | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100226402; called by muse, mutect2, varscan2
- ADAM28 | c.1252G>A p.G418R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99740016; called by muse, mutect2
- AKT3 | c.455A>G p.K152R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs1426791205, COSV99797126; called by muse, mutect2, varscan2
- ALMS1 | c.3150C>G p.Y1050* | Nonsense Mutation (SNP) | VAF 75/258 reads (29%) | catalogued as CM156213, COSV100043989; called by muse, mutect2, varscan2
- ARID5B | c.1159A>G p.S387G | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1170562366, COSV99690594; called by muse, mutect2, varscan2
- BZW2 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV51755684; called by muse, mutect2
- C12orf71 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as COSV101460566; called by muse, mutect2, varscan2
- C2CD5 | c.2785G>A p.A929T | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100449111; called by muse, mutect2, varscan2
- C2orf78 | c.2230C>T p.R744C | Missense Mutation (SNP) | VAF 87/303 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs368168109, COSV68518427; called by muse, mutect2, varscan2
- CDH9 | c.2210C>T p.T737M | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1346865409, COSV50303173, COSV50488057; called by muse, mutect2, varscan2
- CEP170 | c.1271T>C p.V424A | Missense Mutation (SNP) | VAF 65/279 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100318016; called by muse, mutect2, varscan2
- CIC | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747433677, COSV99360404; called by muse, mutect2, varscan2
- CLASRP | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs957979300, COSV99674202; called by muse, mutect2, varscan2
- CLDN17 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.232); catalogued as COSV99729459; called by muse, mutect2, varscan2
- CRISPLD2 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.166); catalogued as rs140773433; called by muse, mutect2, varscan2
- CTIF | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as rs202032754, COSV56484793; called by muse, varscan2
- DNAJC14 | c.1073G>A p.W358* | Nonsense Mutation (SNP) | VAF 30/98 reads (31%) | catalogued as COSV100423769; called by muse, mutect2, varscan2
- DPPA4 | c.444dup p.L149Ifs*14 | Frame Shift Ins (INS) | VAF 44/130 reads (34%) | catalogued as rs762470455; called by mutect2, varscan2
- EPOR | c.1145G>A p.S382N | Missense Mutation (SNP) | VAF 51/72 reads (71%) | SIFT tolerated (0.27); PolyPhen benign (0.107); catalogued as COSV99710334; called by muse, mutect2, varscan2
- EYS | c.1270T>A p.W424R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.956); catalogued as COSV100677240, COSV60998702; called by muse, varscan2
- FAT1 | c.5080C>T p.Q1694* | Nonsense Mutation (SNP) | VAF 65/96 reads (68%) | catalogued as COSV101499251; called by muse, mutect2, varscan2
- GRIA1 | c.1021C>A p.L341M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.4); catalogued as COSV99602742; called by muse, mutect2, varscan2
- HCN4 | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs373284500; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDAC10 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as rs777233310, COSV99299745; called by muse, mutect2, varscan2
- HTR1B | c.694T>G p.Y232D | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100885515; called by muse, mutect2, varscan2
- HTR5A | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.041); catalogued as rs1350441527, COSV55282641; called by muse, mutect2, varscan2
- IGF1R | c.2824G>A p.V942I | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs541998637, COSV51418035; called by muse, mutect2
- INO80 | c.4547C>T p.S1516F | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as rs1335441007, COSV100732101; called by muse, mutect2, varscan2
- KEAP1 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50648926; called by muse, mutect2, varscan2
- KIAA1217 | c.673A>T p.K225* | Nonsense Mutation (SNP) | VAF 43/128 reads (34%) | catalogued as COSV100908477; called by muse, mutect2, varscan2
- KIDINS220 | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99876585; called by muse, mutect2, varscan2
- KNDC1 | c.4222G>A p.G1408S | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs201175312, COSV58842316; called by muse, mutect2, varscan2
- LRFN2 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1339295764, COSV57834331; called by muse, mutect2, varscan2
- LTB4R2 | c.397G>A p.A133T (on ENST00000528054; = p.A102T on NM_019839.5) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs752726999, COSV99351233; called by muse, mutect2, varscan2
- NDST4 | c.1199T>G p.I400S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.026); catalogued as COSV99998126; called by muse, mutect2, varscan2
- NOTCH2 | c.5366G>A p.W1789* | Nonsense Mutation (SNP) | VAF 33/133 reads (25%) | catalogued as COSV99867224; called by muse, mutect2, varscan2
- OR2A2 | c.364T>C p.Y122H | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV101286680; called by muse, mutect2, varscan2
- PCDH7 | c.1886T>C p.V629A | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100688723; called by muse, mutect2, varscan2
- PCDHB12 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.902); catalogued as rs371376851, COSV99507953; called by muse, mutect2, varscan2
- PEAR1 | c.27_29del p.L11del | In Frame Del (DEL) | VAF 46/150 reads (31%) | catalogued as rs373675759; called by mutect2, pindel, varscan2
- PKHD1L1 | c.5512C>T p.P1838S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758884975, COSV101006945; called by muse, mutect2, varscan2
- PKHD1L1 | c.7292A>G p.E2431G | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV101006946; called by muse, mutect2, varscan2
- PLCL1 | c.1948G>T p.D650Y | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70821526; called by muse, mutect2, varscan2
- PREX1 | c.2983C>T p.R995C | Missense Mutation (SNP) | VAF 96/154 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs1409404227, COSV100906879; called by muse, mutect2, varscan2
- PSPC1 | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 115/335 reads (34%) | catalogued as CM142559, COSV58890729; called by muse, mutect2, varscan2
- QRICH1 | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100455230; called by muse, mutect2, varscan2
- RANBP17 | c.625C>G p.Q209E | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101206409; called by muse, mutect2, varscan2
- RC3H1 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99281860; called by muse, mutect2, varscan2
- RYR1 | c.13519G>A p.E4507K | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as rs978180266, COSV100614475, COSV62107833; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC24A4 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs748090494, COSV100104560; called by muse, mutect2, varscan2
- SLC7A3 | c.1730G>A p.G577D | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99979911; called by muse, mutect2, varscan2
- SLK | c.2857G>A p.A953T | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV100212184; called by muse, mutect2, varscan2
- TENM1 | c.7604T>C p.V2535A | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.725); catalogued as COSV100951185; called by muse, mutect2, varscan2
- TET2 | c.3155A>G p.K1052R | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as COSV99485205; called by muse, varscan2
- TTC8 | c.1100G>A p.R367Q (on ENST00000338104 / NM_001288781.1; = p.R351Q on NM_144596.4) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs779617849, COSV57627864, COSV57630447; called by muse, mutect2, varscan2
- UBE2L3 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 76/120 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV100641576; called by muse, varscan2
- USP47 | c.2951G>A p.G984E (on ENST00000399455 / NM_001372095.1; = p.G896E on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100360030; called by muse, mutect2, varscan2
- VN1R1 | c.143C>A p.S48* | Nonsense Mutation (SNP) | VAF 28/101 reads (28%) | catalogued as COSV100320781, COSV58091370; called by muse, mutect2, varscan2
- WDTC1 | c.232C>T p.H78Y | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs1236954121, COSV100089647; called by muse, mutect2, varscan2
- WWC3 | c.3274G>A p.V1092I | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs767870909, COSV101081924; called by muse, mutect2, varscan2
- ZCCHC8 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs747163693, COSV100288897; called by muse, mutect2, varscan2
- ZFR | c.2398C>G p.L800V | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99416677; called by muse, mutect2, varscan2
- ZNF45 | c.1915C>A p.P639T | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99524010; called by muse, mutect2, varscan2
- ACTL6A | c.1253_1255del p.E418del | In Frame Del (DEL) | VAF 9/72 reads (13%) | called by pindel, varscan2
- PCDH12 | c.1761_1774del p.L588Rfs*12 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | called by mutect2, pindel, varscan2
- BTK | c.78G>A p.K26= | Silent (SNP) | VAF 100/310 reads (32%) | catalogued as COSV100437984, COSV58122965; called by muse, mutect2, varscan2
- CA10 | c.693T>C p.S231= | Silent (SNP) | VAF 41/124 reads (33%) | catalogued as rs1332185177, COSV99565577; called by muse, mutect2, varscan2
- DCAF4L1 | c.345C>T p.Y115= | Silent (SNP) | VAF 42/110 reads (38%) | catalogued as rs765518456, COSV60787146; called by muse, mutect2, varscan2
- ERMAP | c.1314C>T p.L438= | Silent (SNP) | VAF 48/148 reads (32%) | catalogued as COSV100072428, COSV104407395; called by muse, mutect2, varscan2
- FARP1 | c.2946G>A p.S982= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as rs766113572, COSV60344159; called by muse, mutect2, varscan2
- MED12L | c.4567C>T p.L1523= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV99855034; called by muse, mutect2, varscan2
- MPP6 | c.1371G>A p.A457= | Silent (SNP) | VAF 65/181 reads (36%) | catalogued as rs778913694, COSV56036823; called by muse, mutect2, varscan2
- NOD2 | c.1146C>T p.D382= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as rs104895476, CM050186; called by muse, mutect2, varscan2
- NOD2 | c.2436T>A p.P812= | Silent (SNP) | VAF 98/259 reads (38%) | catalogued as COSV100318912; called by muse, mutect2, varscan2
- NT5C1B | c.966C>T p.D322= (on ENST00000359846 / NM_001199086.2; = p.D262= on NM_033253.4) | Silent (SNP) | VAF 84/270 reads (31%) | catalogued as COSV58398950; called by muse, mutect2, varscan2
- PIWIL2 | c.2835G>A p.K945= | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as rs750792356, COSV100769580; called by muse, mutect2, varscan2
- PLXNA3 | c.3738T>A p.T1246= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as COSV100860294; called by muse, mutect2, varscan2
- PPP1R12B | c.2196G>C p.T732= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV99295394; called by muse, mutect2, varscan2
- PTCHD3 | c.726G>A p.A242= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs768736791, COSV71256499; called by muse, mutect2, varscan2
- RTP2 | c.486C>A p.I162= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100833038; called by muse, mutect2, varscan2
- SNAPC4 | c.1143G>A p.G381= | Silent (SNP) | VAF 44/130 reads (34%) | catalogued as COSV100047759; called by muse, mutect2, varscan2
- SORCS2 | c.2796C>T p.G932= | Silent (SNP) | VAF 64/162 reads (40%) | catalogued as rs371704709, COSV100214239; called by muse, mutect2, varscan2
- TNNT3 | c.120C>T p.T40= (on ENST00000397301 / NM_001367846.1; = p.T29= on NM_006757.4) | Silent (SNP) | VAF 48/172 reads (28%) | catalogued as rs767746676, COSV99548847; called by muse, mutect2, varscan2
- ZFP14 | c.1494C>T p.H498= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as COSV54204661; called by muse, mutect2, varscan2
- ZNF516 | c.1761C>T p.D587= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV101487383, COSV99069442; called by muse, mutect2, varscan2
- FOLH1B | n.1385T>C | RNA (SNP) | VAF 50/175 reads (29%) | called by muse, mutect2, varscan2
